Somatic mutation profile of tumor specimen ALCH-B5QD-TTP1-A (aliquot ALCH-B5QD-TTP1-A-1-0-D-A87U-36) from ALCHEMIST case ALCH-B5QD, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 74.6 years (27,247 days).
Specimen ALCH-B5QD-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a63577e6-f794-4f77-ae23-ebc373872a37.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B5QD-NB1-A (Blood Derived Normal), aliquot ALCH-B5QD-NB1-A-2-0-D-A87U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e267ebd-1734-4bc8-a951-fccaab3ade7a

The open-access MAF lists 25 somatic variants for this specimen: 11 protein-altering or splice-affecting, 10 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 10, Intron 2, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DAB2 | c.775G>A p.G259S | Missense Mutation (SNP) | VAF 20/328 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.492); catalogued as rs776688156, COSV57916686; called by muse, mutect2
- ELANE | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 17/248 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1243076107; called by muse, mutect2
- FAM83G | c.652A>T p.M218L | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.095); catalogued as rs1459353525; called by muse, mutect2
- USP32 | c.3581A>G p.Y1194C | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.043); catalogued as rs1190532595; called by muse, mutect2
- GRAP | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- GRIN2A | c.1844A>T p.N615I | Missense Mutation (SNP) | VAF 21/300 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GSTO1 | c.515T>A p.M172K | Missense Mutation (SNP) | VAF 15/241 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IGLV7-43 | c.238C>G p.P80A | Missense Mutation (SNP) | VAF 14/298 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2
- NKD1 | c.977C>T p.A326V | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2
- RBP5 | c.106C>A p.L36M | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.226); called by muse, mutect2
- WNT8A | c.31C>A p.L11M | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.005); called by muse, mutect2
- BAZ2A | c.2139C>T p.S713= | Silent (SNP) | VAF 12/401 reads (3%) | called by muse, mutect2
- DBNDD2 | c.183C>T p.A61= | Silent (SNP) | VAF 10/139 reads (7%) | called by muse, mutect2
- DIAPH3 | c.1684T>C p.L562= (on ENST00000400324 / NM_001042517.2; = p.L299= on NM_030932.3) | Silent (SNP) | VAF 8/125 reads (6%) | called by muse, mutect2
- DYNC1H1 | c.13059C>T p.D4353= | Silent (SNP) | VAF 16/297 reads (5%) | catalogued as rs773232010; ClinVar: likely benign; called by muse, mutect2
- KLK6 | c.129C>T p.G43= | Silent (SNP) | VAF 12/193 reads (6%) | called by muse, mutect2
- PCYOX1L | c.1290C>T p.S430= | Silent (SNP) | VAF 5/53 reads (9%) | called by muse, mutect2
- RBP5 | c.105G>A p.L35= | Silent (SNP) | VAF 14/126 reads (11%) | called by muse, mutect2
- SPDYE3 | c.1528C>A p.R510= | Silent (SNP) | VAF 35/407 reads (9%) | catalogued as rs376445936; called by muse, mutect2
- UGT2B15 | c.678A>G p.Q226= | Silent (SNP) | VAF 21/328 reads (6%) | called by muse, mutect2
- ZNF221 | c.1311A>T p.R437= | Silent (SNP) | VAF 8/124 reads (6%) | called by muse, mutect2
- ALDH2 | c.115-6219C>A | Intron (SNP) | VAF 12/156 reads (8%) | called by muse, mutect2
- GPR137B | c.-21C>T | 5'UTR (SNP) | VAF 3/21 reads (14%) | catalogued as rs1383908152; called by muse, varscan2
- MAP11 | c.724+73C>T | Intron (SNP) | VAF 10/236 reads (4%) | called by muse, mutect2
- TSHZ2 | c.*1897C>T | 3'UTR (SNP) | VAF 32/724 reads (4%) | called by muse, mutect2
